HCMI case HCM-BROD-0683-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4776d0d4-489f-4fb4-9ab3-03d6790baa66

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Dead; Days to death: 436 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,107 days); Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lung, NOS / Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 410 days (1.1 years); Days to treatment end: 436 days (1.2 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: metastasis; Age at diagnosis: 55.0 years (20,107 days); Satellite nodule present: Absent.
   Pathology details: Lymph nodes positive: 4; Lymph nodes tested: 7; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 436 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- NRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 110 kg; Height: 174 cm; BMI: 36.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0683-C43-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0683-C43-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 3.
